Somatic mutation profile of tumor specimen TCGA-QG-A5Z1-01A (aliquot TCGA-QG-A5Z1-01A-11D-A28G-10) from TCGA case TCGA-QG-A5Z1, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 71.8 years (26,220 days).
Specimen TCGA-QG-A5Z1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5a7d4d8-b89e-470b-94fb-777dfb4dc987.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QG-A5Z1-10A (Blood Derived Normal), aliquot TCGA-QG-A5Z1-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be7264a6-ec4e-4b2f-acb4-3b167d159464

The open-access MAF lists 109 somatic variants for this specimen: 83 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 22, Nonsense Mutation 9, Frame Shift Del 4, Splice Region 1, Intron 1, 5'Flank 1, 5'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IMPG1 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 41/102 reads (40%) | catalogued as rs200651043, COSV64054288; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLR3A | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as rs141659018, COSV104428130; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 17/27 reads (63%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- ADD3 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs374723508; called by muse, mutect2, varscan2
- AHNAK2 | c.13235G>T p.G4412V | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); catalogued as rs764108680, COSV60917952; called by muse, mutect2, varscan2
- APC | c.3502G>T p.E1168* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as CM010754, COSV57356114; called by muse, mutect2, varscan2
- ARHGAP32 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs764660671; called by muse, mutect2, varscan2
- ASB18 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV58234368; called by muse, mutect2, varscan2
- B3GALT5 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs372607334; called by muse, mutect2, varscan2
- CD93 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs761695801, COSV55663392; called by muse, mutect2, varscan2
- CECR2 | c.3970G>A p.A1324T (on ENST00000342247 / NM_001290047.2; = p.A1140T on NM_001290046.1) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs897079322, COSV52849253; called by muse, mutect2, varscan2
- CRYGC | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs763807736, COSV52205372; called by muse, mutect2, varscan2
- FAT3 | c.5419C>T p.R1807W | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs566312497, COSV53116745; called by muse, mutect2, varscan2
- FAT4 | c.5761G>A p.G1921S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs370906656, COSV58694895; called by muse, mutect2, varscan2
- FBLN2 | c.2603G>A p.R868H | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs377251898; called by muse, mutect2, varscan2
- FBN2 | c.2242A>C p.N748H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV52519709; called by muse, mutect2, varscan2
- FBXO27 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs771973559; called by muse, mutect2, varscan2
- FLNB | c.6073G>A p.V2025M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774677814, COSV55877028; called by muse, mutect2, varscan2
- GIMAP4 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs374272297; called by muse, mutect2, varscan2
- GPR78 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs927273114; called by muse, mutect2, varscan2
- GTF2I | c.1241dup p.Y414* (on ENST00000573035 / NM_032999.4; = p.Y373* on NM_001518.5) | Nonsense Mutation (INS) | VAF 72/328 reads (22%) | catalogued as rs1404561582; called by mutect2, pindel, varscan2
- HTRA3 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.105); catalogued as rs930263991, COSV56471489; called by muse, mutect2, varscan2
- IGLV3-22 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs530284832; called by muse, mutect2, varscan2
- IGSF21 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775253227; called by muse, mutect2, varscan2
- IL20RA | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs751829168; called by muse, mutect2, varscan2
- ITPK1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as rs767945252, COSV50894878, COSV50896361; called by muse, mutect2, varscan2
- JAG1 | c.2663G>T p.G888V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54756656; called by muse, mutect2, varscan2
- KCNB2 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as rs770305852, COSV73050540; called by muse, mutect2, varscan2
- KLHL2 | c.1211C>A p.A404D | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56984085; called by muse, mutect2, varscan2
- KRTAP11-1 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 70/194 reads (36%) | catalogued as rs544655287; called by muse, mutect2, varscan2
- LRP1B | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101250474; called by muse, mutect2, varscan2
- LRRC18 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs138127999; called by muse, mutect2, varscan2
- LRWD1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747690267, COSV99484437; called by muse, mutect2, varscan2
- MED26 | c.923del p.D308Vfs*113 | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | catalogued as COSV54660758; called by mutect2, pindel, varscan2
- NINL | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs750950764, COSV54001858; called by muse, mutect2, varscan2
- NLGN1 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 65/122 reads (53%) | catalogued as rs1246921076, COSV64341360; called by muse, mutect2, varscan2
- OR4N5 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs143406902; called by muse, mutect2, varscan2
- OXA1L | c.1316G>A p.R439Q (on ENST00000285848; = p.R379Q on NM_005015.5) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs560027042, COSV99591352; called by muse, mutect2, varscan2
- PACSIN1 | c.1169del p.V390Gfs*97 | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | catalogued as COSV55060534; called by mutect2, pindel, varscan2
- PKLR | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV61360299; called by muse, mutect2, varscan2
- PRAMEF1 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 84/409 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs762228466, COSV60004959; called by muse, mutect2, varscan2
- PSPN | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as rs367629407; called by muse, mutect2, varscan2
- RNF26 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs1323745826; called by muse, mutect2, varscan2
- RTP1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.163); catalogued as rs772437664, COSV56617613; called by muse, mutect2, varscan2
- SLC12A5 | c.1837C>T p.R613C (on ENST00000454036 / NM_001134771.2; = p.R590C on NM_020708.5) | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54804588; called by muse, mutect2
- SLC4A2 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776189342, COSV52539595; called by mutect2, varscan2
- SPECC1L | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1186415259; called by muse, mutect2, varscan2
- SYNE3 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as rs1488537327; called by muse, mutect2, varscan2
- TBC1D8 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1404729374, COSV65213342; called by muse, mutect2, varscan2
- TIMELESS | c.3124G>A p.V1042I | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as rs745492833; called by muse, mutect2, varscan2
- TNP2 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs200118105, COSV57129650; called by muse, mutect2, varscan2
- TTBK1 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV52492335; called by muse, mutect2
- ZBED4 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1488484952, COSV53465503; called by muse, mutect2, varscan2
- ZFPM2 | c.1411A>C p.K471Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65874117; called by muse, mutect2, varscan2
- ZFPM2 | c.2649G>T p.Q883H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV101023174, COSV65874124; called by muse, mutect2, varscan2
- ZNF155 | c.557G>C p.C186S | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.881); catalogued as COSV54207924; called by muse, mutect2, varscan2
- ZNF628 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99219992; called by muse, mutect2
- ZNF781 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs772286028, COSV62201701; called by muse, mutect2, varscan2
- ZNF8 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs750570090; called by muse, mutect2, varscan2
- ACTN4 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- BSN | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- CSMD3 | c.3943A>C p.M1315L (on ENST00000297405 / NM_001363185.1; = p.M1211L on NM_052900.3) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- DCAF12 | c.1023T>G p.S341R | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- DDX19A | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DHX9 | c.2243A>G p.Y748C | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRYL | c.8145G>A p.Q2715= | Splice Region (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- ITIH6 | c.3446C>A p.T1149K | Missense Mutation (SNP) | VAF 103/131 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JAG1 | c.3160G>T p.E1054* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | called by muse, varscan2
- MTUS2 | c.1724C>A p.T575N | Missense Mutation (SNP) | VAF 95/166 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MUC17 | c.3514G>C p.V1172L | Missense Mutation (SNP) | VAF 21/380 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2
- NUP205 | c.5985C>G p.F1995L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PCDH7 | c.2669A>T p.K890M | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PEAR1 | c.2990del p.P997Lfs*65 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- PEX7 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAPGEF2 | c.1560A>C p.K520N | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SLC6A5 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, varscan2
- SMURF1 | c.854del p.F285Sfs*16 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- SYNE2 | c.11153A>C p.E3718A | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- THRB | c.1117C>T p.L373F | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNDC2 | c.252G>T p.Q84H (on ENST00000306084 / NM_001098529.2; = p.Q17H on NM_032243.6) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- VEGFB | c.375-2_377del p.X125_splice | Splice Site (DEL) | VAF 24/44 reads (55%) | called by pindel, varscan2
- ZNF180 | c.37A>C p.S13R | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF765 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CHRDL1 | c.1113C>T p.H371= (on ENST00000372045; = p.H377= on NM_145234.4) | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as rs76506792; called by muse, mutect2, varscan2
- CHST8 | c.273G>A p.A91= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs765158776, COSV52857855; called by muse, mutect2, varscan2
- CNTNAP5 | c.1596C>T p.S532= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as COSV70477568; called by muse, mutect2, varscan2
- COPS2 | c.694C>T p.L232= | Silent (SNP) | VAF 84/101 reads (83%) | catalogued as rs780336002; called by muse, mutect2, varscan2
- DCLK1 | c.93G>A p.P31= | Silent (SNP) | VAF 63/108 reads (58%) | catalogued as rs1304828842; called by muse, mutect2, varscan2
- DST | c.14469C>A p.I4823= (on ENST00000361203 / NM_001374722.1; = p.I2411= on NM_015548.5) | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV55020136; called by muse, mutect2, varscan2
- INTS6L | c.621C>T p.S207= | Silent (SNP) | VAF 68/85 reads (80%) | catalogued as rs782099771, COSV100877993, COSV66084660; called by muse, mutect2, varscan2
- KCTD15 | c.60C>A p.G20= | Silent (SNP) | VAF 47/134 reads (35%) | called by muse, mutect2, varscan2
- KRT84 | c.1530C>T p.G510= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs550159082; called by muse, mutect2, varscan2
- OR2T2 | c.954G>A p.A318= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs200152335, COSV61619133; called by mutect2, varscan2
- PAPPA2 | c.1366C>T p.L456= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV62779796; called by muse, mutect2
- PEX5L | c.49C>T p.L17= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV55850170; called by muse, mutect2, varscan2
- PLCD4 | c.2286C>G p.S762= | Silent (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- PROSER3 | c.540G>A p.K180= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1050761635; called by muse, mutect2, varscan2
- PRXL2C | c.207C>T p.Y69= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs763910204; called by muse, mutect2, varscan2
- RC3H2 | c.1584C>T p.G528= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as rs1191168207, COSV61799148; called by muse, mutect2, varscan2
- SERPINB6 | c.1008C>T p.H336= (on ENST00000612421 / NM_001271823.2; = p.H317= on NM_004568.6) | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as COSV59566159; called by muse, mutect2
- SETD1B | c.957C>T p.D319= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs543855650, COSV57355152; called by muse, mutect2, varscan2
- SIGLEC14 | c.978C>A p.G326= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- SOX17 | c.1203C>T p.D401= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs367836623; called by muse, mutect2, varscan2
- TAF1L | c.2838T>C p.V946= | Silent (SNP) | VAF 12/284 reads (4%) | catalogued as COSV99644581; called by muse, mutect2
- ZNF835 | c.1464G>A p.A488= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV73379228; called by muse, mutect2, varscan2
- ATOH7 | c.-300T>A | 5'UTR (SNP) | VAF 40/107 reads (37%) | catalogued as rs754779263, COSV101028492; called by muse, mutect2, varscan2
- DTNBP1 | c.811+62G>A | Intron (SNP) | VAF 8/158 reads (5%) | catalogued as COSV100160327, COSV100160738; called by muse, mutect2
- MIR130B | n.41C>T | RNA (SNP) | VAF 11/97 reads (11%) | catalogued as rs754895823; called by muse, mutect2, varscan2
- OR1K1 | chr9:122798529 G>T | 5'Flank (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
